Somatic mutation profile of tumor specimen TCGA-D1-A1NU-01A (aliquot TCGA-D1-A1NU-01A-11D-A14G-09) from TCGA case TCGA-D1-A1NU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.7 years (27,272 days).
Specimen TCGA-D1-A1NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22e60882-ca71-4a93-8d8c-6749796ce7c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NU-10A (Blood Derived Normal), aliquot TCGA-D1-A1NU-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/701ca96f-5053-4d77-8e8c-a372c32b42c3

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 22, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1057519803, COSV57246350, COSV57249681; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 41/64 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TAF1 | c.3445C>T p.R1149C (on ENST00000373790 / NM_138923.4; = p.R1170C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569301036, CM151033, COSV52106881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACKR4 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV51442044; called by muse, mutect2, varscan2
- ADPRHL1 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1190753727, COSV60260620; called by muse, mutect2, varscan2
- AGT | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV64183657; called by muse, mutect2, varscan2
- AKAP9 | c.6709G>C p.E2237Q (on ENST00000359028; = p.E2213Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62338182; called by muse, mutect2, varscan2
- AMER1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57654272; called by muse, mutect2, varscan2
- AP002512.3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs558210028, COSV54405409; called by muse, mutect2, varscan2
- ATF2 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV51367794; called by muse, mutect2, varscan2
- CBFB | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV51996512, COSV52001505; called by muse, mutect2, varscan2
- CLUL1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV58111150; called by muse, mutect2, varscan2
- CRX | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV55756898; called by muse, mutect2, varscan2
- CRYGC | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56408330; called by muse, mutect2, varscan2
- CXorf66 | c.409T>A p.L137I | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV65168890, COSV65169063; called by muse, mutect2, varscan2
- DDX42 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.218); catalogued as COSV63789224; called by muse, mutect2, varscan2
- ECI2 | c.492A>G p.I164M (on ENST00000380118 / NM_206836.3; = p.I134M on NM_006117.2) | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV60984814; called by muse, mutect2, varscan2
- FBN1 | c.5197T>A p.C1733S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57308719; called by muse, mutect2, varscan2
- GABRA3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 44/115 reads (38%) | catalogued as rs777972856, COSV64794901; called by muse, mutect2, varscan2
- GLOD5 | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57488687, COSV57489669; called by muse, mutect2, varscan2
- IL6 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.269); catalogued as COSV51732188; called by muse, mutect2, varscan2
- KCNA6 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54973879; called by muse, mutect2, varscan2
- KRTAP5-11 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV59367526; called by muse, mutect2, varscan2
- LGI2 | c.485+2T>G p.X162_splice | Splice Site (SNP) | VAF 43/166 reads (26%) | catalogued as COSV66122265; called by muse, mutect2, varscan2
- MAB21L1 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59758741; called by muse, mutect2
- MAB21L2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV58260725; called by muse, mutect2, varscan2
- MMP16 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54149872; called by muse, mutect2, varscan2
- MROH2B | c.1699A>G p.T567A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68180818; called by muse, mutect2, varscan2
- MTOR | c.5921A>G p.Y1974C | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63868192; called by muse, mutect2, varscan2
- MYOM2 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV50701870; called by muse, mutect2, varscan2
- NRDC | c.2507A>T p.H836L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61401393; called by muse, mutect2, varscan2
- OPN1LW | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV64063771; called by muse, mutect2, varscan2
- OR4S2 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs150655948; called by muse, mutect2
- PCDHGB5 | c.1365_1368del p.S456Yfs*23 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs778579612; called by mutect2, pindel, varscan2
- PCNX4 | c.1436G>A p.G479E (on ENST00000406854 / NM_001330177.2; = p.G245E on NM_022495.5) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58302223; called by muse, mutect2, varscan2
- PCOLCE2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55997347; called by muse, mutect2
- PDE11A | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV53685341; called by muse, mutect2, varscan2
- PDZD11 | c.279A>C p.Q93H | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52103190; called by muse, mutect2, varscan2
- PDZRN3 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55190666; called by muse, mutect2, varscan2
- PIGB | c.1207A>T p.T403S | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51241080; called by muse, mutect2, varscan2
- PLD3 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV62924124; called by muse, mutect2, varscan2
- POLQ | c.6052C>A p.P2018T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV51745364; called by muse, mutect2, varscan2
- PRCC | c.810A>T p.E270D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV54854763; called by muse, mutect2, varscan2
- PSG1 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as COSV54944074, COSV54954958; called by muse, mutect2, varscan2
- PTK2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1179929431, COSV61782183; called by muse, mutect2, varscan2
- PZP | c.2773A>G p.M925V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54353944; called by muse, mutect2, varscan2
- RFLNB | c.206G>T p.C69F | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61239034; called by muse, mutect2, varscan2
- RHOJ | c.207C>A p.H69Q | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV57456356; called by muse, mutect2, varscan2
- SAFB2 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs1051172357, COSV53040506; called by muse, mutect2, varscan2
- SF1 | c.1081A>T p.T361S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.678); catalogued as COSV57111148; called by muse, mutect2, varscan2
- SGSM1 | c.1673G>T p.C558F | Missense Mutation (SNP) | VAF 80/105 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68508620; called by muse, mutect2, varscan2
- SHISA2 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60110108; called by muse, mutect2, varscan2
- SIGLEC5 | c.1414A>T p.R472* | Nonsense Mutation (SNP) | VAF 41/53 reads (77%) | catalogued as COSV55777248; called by muse, mutect2, varscan2
- SLC15A1 | c.1067+1G>A p.X356_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | catalogued as rs534049646, COSV64729831; called by muse, mutect2, varscan2
- SLC4A4 | c.1567C>G p.L523V (on ENST00000264485 / NM_001098484.3; = p.L479V on NM_003759.4) | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1560533196, COSV52614058; called by muse, mutect2, varscan2
- SLITRK2 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV59422774; called by muse, mutect2, varscan2
- SPINDOC | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV53691840; called by muse, mutect2, varscan2
- SPRY3 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV57141783; called by muse, mutect2, varscan2
- SVIL | c.4041G>C p.E1347D (on ENST00000355867 / NM_021738.3; = p.E921D on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63439495; called by muse, mutect2, varscan2
- SYNE1 | c.24717C>G p.H8239Q (on ENST00000367255 / NM_182961.4; = p.H8168Q on NM_033071.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs201548223; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TASOR2 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1199796488, COSV60165314; called by muse, mutect2, varscan2
- TCF12 | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1347322943, COSV51003294; called by muse, mutect2, varscan2
- TTC30A | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63100425; called by muse, mutect2, varscan2
- TTN | c.42074T>C p.V14025A (on ENST00000591111; = p.V6601A on NM_003319.4) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | PolyPhen probably damaging (0.99); catalogued as COSV59873760; called by muse, mutect2, varscan2
- USP32 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs769729040, COSV56263754; called by muse, mutect2, varscan2
- WWC1 | c.2010G>C p.E670D | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54645436; called by muse, mutect2, varscan2
- ZNF41 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV57440889; called by muse, mutect2, varscan2
- ZNF529 | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV61899292; called by muse, mutect2, varscan2
- ZNFX1 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV65573488; called by muse, mutect2, varscan2
- AP2B1 | c.2093C>A p.T698K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- CRYZ | c.48del p.F16Lfs*7 | Frame Shift Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- SLC1A5 | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- SLITRK4 | c.1449_1456del p.N483Kfs*15 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- TTC30B | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- BACH2 | c.1791G>A p.S597= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs755356618, COSV57583686; called by muse, mutect2, varscan2
- CC2D2A | c.1353T>A p.T451= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV67502080; called by muse, mutect2, varscan2
- CDHR5 | c.1264C>T p.L422= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs375394361; called by muse, mutect2, varscan2
- CNNM4 | c.969C>G p.L323= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as COSV100998845, COSV65660179; called by muse, mutect2, varscan2
- COL11A1 | c.1611T>A p.T537= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV62172211; called by muse, mutect2, varscan2
- DBH | c.840C>T p.S280= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs894934479, COSV55039634; called by muse, mutect2
- EIF3A | c.2371T>C p.L791= | Silent (SNP) | VAF 86/213 reads (40%) | catalogued as COSV64960419; called by muse, mutect2, varscan2
- HNF4G | c.81C>T p.S27= (on ENST00000354370 / NM_001330561.2; = p.S74= on NM_004133.5) | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV62965515; called by muse, mutect2, varscan2
- HUWE1 | c.3114C>T p.I1038= | Silent (SNP) | VAF 57/101 reads (56%) | catalogued as rs781848587, COSV53333784; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV4-61 | c.66G>A p.Q22= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs782146019; called by muse, varscan2
- JMJD1C | c.1692C>T p.S564= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs1221840900, COSV67857500; called by muse, mutect2, varscan2
- MAST3 | c.2484C>A p.P828= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53217303; called by muse, mutect2, varscan2
- MGAT5B | c.1860C>T p.Y620= (on ENST00000569840 / NM_001199172.2; = p.Y618= on NM_144677.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56924716; called by muse, mutect2
- PARD3 | c.2412C>T p.A804= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs781058544, COSV60744737; called by muse, mutect2, varscan2
- PELI1 | c.864A>T p.T288= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV62729343; called by muse, mutect2, varscan2
- SMARCA4 | c.1590C>G p.L530= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV60786057; called by muse, mutect2, varscan2
- STH | c.228T>C p.S76= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV52236811; called by muse, mutect2, varscan2
- SYCP2 | c.3162C>T p.I1054= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV62765723; called by muse, mutect2, varscan2
- TARS2 | c.1809C>T p.C603= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs752424999, COSV60871590; called by muse, mutect2, varscan2
- TPTE | c.96C>T p.T32= | Silent (SNP) | VAF 55/267 reads (21%) | catalogued as rs571891150; called by muse, mutect2, varscan2
- TRIO | c.8322G>A p.L2774= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV59988536, COSV59991378; called by muse, mutect2, varscan2
- ZSCAN10 | c.588G>T p.V196= (on ENST00000252463; = p.V251= on NM_032805.3) | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV52966754; called by muse, mutect2, varscan2
- CTSL3P | n.597C>T | RNA (SNP) | VAF 65/87 reads (75%) | catalogued as rs200255248; called by muse, mutect2, varscan2
- HERC2P3 | n.1969G>A | RNA (SNP) | VAF 6/49 reads (12%) | catalogued as rs1348003877; called by mutect2, varscan2
- RUSC1 | c.-87+106C>G | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as COSV52738047; called by muse, mutect2, varscan2
